CCDI case PBBVUF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/9193d469-463d-4c15-a1c2-d3d795b7bbbd

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Eyelid; Age at diagnosis: 8.1 years (2,954 days).

Biospecimens (3 samples)
- Sample 0DIQZO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIR08: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIR1Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
